Gene-level copy-number profile of tumor specimen TCGA-NA-A5I1-01A from TCGA case TCGA-NA-A5I1, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIB; Age at diagnosis: 80.3 years (29,329 days).
Specimen TCGA-NA-A5I1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.50931435-7595-46ce-83ea-af606ffbe4a2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NA-A5I1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f52c46c-2753-4973-8ba5-04a60b5c4616

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 15,686; copy number 2: 38,030; copy number 3: 3,881; copy number 4: 2,040; copy number 5: 108; copy number 7: 59.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NA-A5I1-01A-21D-A28Q-01): tumor purity 0.82, ploidy 3.85, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 167 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,345,691–2,242,276, 24 genes, copy number 7 (within-gene range 2–7): UVSSA, AC078852.2, AC078852.1, NKX1-1, AC147067.2, AC147067.1, FAM53A, Y_RNA, SLBP, AC016773.1, TACC3, TMEM129, FGFR3, LETM1, NSD2, SCARNA22, NELFA, MIR943, C4orf48, NAT8L, POLN, HAUS3, AL136360.1, AL136360.2.
- chr19:38,433,691–39,555,356, 64 genes, copy number 5 (broad region; genes not listed).
- chr20:31,819,308–32,743,567, 35 genes, copy number 7: MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1, NOL4L, AL034550.1, AL034550.3, AL034550.2, AL133343.2, NOL4L-DT, AL133343.1, C20orf203, FO393400.1, BAK1P1, COMMD7.
- chr22:38,056,311–38,903,794, 44 genes, copy number 5: PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1, PLA2G6, AL022322.2, MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E, TPTEP2-CSNK1E, TPTEP2, Z98749.1, Z97056.2, Z97056.1, KCNJ4, Z97056.3, KDELR3, DDX17, DMC1, RPS29P31, FAM227A, CBY1, AL021707.4, AL021707.2, AL021707.9, TOMM22, JOSD1, GTPBP1, PRDX3P1, AL021707.5, SUN2, AL021707.3, AL021707.8, AL021707.1, AL021707.6, AL021707.7, DNAL4, NPTXR, CBX6, AL022318.5.

Autosomal genes at a single copy (total copy number 1): 15,686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
